TCGA case TCGA-42-2582 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7922df77-f09a-488c-a1be-58646ceb9b3e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Dead; Days to death: 1,447 days (4.0 years).

Diagnoses (6)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 49.2 years (17,961 days); Year of diagnosis: 2009; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,447 days (4.0 years).
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 36 days; Days to treatment end: 36 days; Number of cycles: 1; Treatment dose: 325 mg; Prescribed dose: 325; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 185 days; Number of cycles: 7; Treatment dose: 1,260 mg; Prescribed dose: 180; Prescribed dose units: mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 57 days; Days to treatment end: 184 days; Number of cycles: 6; Treatment dose: 945 mg; Prescribed dose: 135; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 232 days; Number of cycles: 7; Treatment dose: 1,440 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 240; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 232 days; Days to treatment end: 560 days (1.5 years); Number of cycles: 6; Treatment dose: 1,453 mg; Prescribed dose: 242; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 640 days (1.8 years); Days to treatment end: 682 days (1.9 years); Number of cycles: 3; Treatment dose: 540 mg; Prescribed dose: 180; Prescribed dose units: mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Days to treatment start: 800 days (2.2 years); Days to treatment end: 955 days (2.6 years); Treatment outcome: Stable Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 50.9 years (18,577 days); Days to diagnosis: 616 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 616 days (1.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 52.1 years (19,034 days); Days to diagnosis: 1,073 days (2.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
4. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 52.1 years (19,034 days); Days to diagnosis: 1,073 days (2.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
5. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 52.4 years (19,140 days); Days to diagnosis: 1,179 days (3.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
6. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 52.4 years (19,140 days); Days to diagnosis: 1,179 days (3.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (8 entries)
- Days to follow up: 435 days (1.2 years); Disease response: With Tumor.
- Day 616 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 616 days (1.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 792 days (2.2 years); Disease response: With Tumor.
- Day 1,073 (post initial treatment): Progression or recurrence: Yes; Days to progression: 1,073 days (2.9 years); Evidence of progression type: Convincing Image Source.
- Day 1,179 (post initial treatment): Progression or recurrence: Yes; Days to progression: 1,179 days (3.2 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,447 days (4.0 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.
- ECOG performance status: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-42-2582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-42-2582-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-42-2582-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-42-2582-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-42-2582-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 4, Route of administrations: Route of administration: IP.
- Drug treatment 5: Regimen number: 02; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 6: Regimen number: 03.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-42-2582-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.
- Pathology outside specification: Pathology Results off Spec.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,447 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,447 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 616 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-42-2582-01A-01D-1043-01): tumor purity 0.75, ploidy 2.12, whole-genome doublings 0.
